Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADC, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADC-01A (Primary Tumor).

[page 1 of 2]
LINICAL DIAGNOSIS: Known HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Central bissectionectomy (segment 5-8)

Organ: Liver (13.1 x 9.5 x 6.2 cm, 267.5 gm)

Gallbladder (10.0 cm in length, 4.0 cm in diameter)

Tissues, labeled as 'portal vein thrombi'

(1.5 x 1.5 x 0.4 cm in aggregates)

Lesion: Hepatic mass

Size: 7.5 x 6.6 x 5.1 cm

Cut surface: Poorly demarcated, pale tan and nodular mass

Gross type: Multinodular confluent

Extent: Confined to the capsule

Resection margin: Not involved, grossly (safety margin: 1.5 cm)

Remaining parenchyme: Cirrhosis

[Gallbladder]

Serosal surface: Yellowish pink and smooth

Mucosal surface: Dark green and velvety, no mural nodule

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4, mass of liver x 4

RM, tumor with resection margin x 1

L, nontumorous liver parenchyme x 1

A, labeled as 'portal vein thrombi' x 1

GB, gallbladder x 1

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

Edmondson-Steiner grade

The worst differentiation III

The major differentiation III

Histologic type: Trabecular and nesting

Fatty change: No

Fibrous capsule formation: Partial

Capsular infiltration: Yes

ICD-0-3

Carcinoma hepatocellular 8170/3

Site Liver C22.0

QW 5/19/14

[page 2 of 2]
Septum formation: No
Surgical resection margin invasion: No
Serosal invasion: No
Portal vein invasion: Yes (separately submitted tissue, labeled as 'portal vein thrombi')
Vascular invasion: Yes
Bile duct invasion: No
Remaining liver parenchyme: Cirrhosis

NOT reported. Gross:

stomach,antrum,scopic,chronic gastritis, h. pylori, associated

Liver, needle ,Chronic hepatitis, HBV associated

liver,ectomy,Hepatocellular carcinoma
T56000, P10, M81703
portal vein thrombi,biopsy,tumor cells present
portal vein thrombi, P50, M80011
gallbladder,ectomy,autolysis
T57000, P10, M54001

DIAGNOSIS:

Liver, segment 5-8, central bissectionectomy:
Hepatocellular carcinoma

Labeled as 'portal vein thrombi', biopsy:
Tumor cells present

Galllbladder, cholecystectomy:

Suggestion :

Source: NCI Genomic Data Commons file a73ca613-9630-4159-8650-895deff75bec (TCGA-DD-AADC.2A33A2FB-4491-43AA-8C6D-8173FB1D2179.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).